Somatic mutation profile of tumor specimen TARGET-10-PARGUZ-09A (aliquot TARGET-10-PARGUZ-09A-01D) from TARGET case TARGET-10-PARGUZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,806 days).
Specimen TARGET-10-PARGUZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1966d9db-9562-493f-b568-34059590f05d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGUZ-10A (Blood Derived Normal), aliquot TARGET-10-PARGUZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b18ea861-6fd2-4251-bba8-2b24ec35c311

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Intron 2, Frame Shift Ins 1, Splice Region 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPE | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as rs1219645806, COSV101291686; called by muse, mutect2
- DTNA | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs773170065, COSV52011286; called by mutect2, varscan2
- KLF8 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1433771646; called by muse, mutect2
- NPHS1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369787477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.1660C>A p.R554S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54776231; called by muse, mutect2
- ZSCAN18 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1223242393; called by muse, mutect2
- ABCC1 | c.4109T>C p.I1370T | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FBN1 | c.7490A>T p.Q2497L | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FEM1C | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- FRMD5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.5723C>A p.A1908D | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- JAK2 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KITLG | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ME3 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- NSUN2 | c.96G>T p.A32= | Splice Region (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- SLC35B3 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMPDL3A | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THRAP3 | c.30dup p.S11Ifs*38 | Frame Shift Ins (INS) | VAF 55/125 reads (44%) | called by mutect2, pindel, varscan2
- WDR6 | c.1801C>A p.L601I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- ANXA1 | c.348G>A p.A116= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs774051268, COSV57410943; called by muse, mutect2, varscan2
- CACNG5 | c.291C>A p.I97= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- FMO2 | c.1311C>T p.D437= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs1286850973; called by muse, mutect2, varscan2
- GABRA2 | c.1095C>T p.N365= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs199645306, COSV100734761; called by muse, mutect2, varscan2
- PDZD2 | c.3093G>A p.S1031= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs779862215; called by muse, mutect2, varscan2
- PSG1 | c.348C>T p.D116= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs137928256, COSV99740008; called by muse, mutect2, varscan2
- TRIL | c.2265G>T p.V755= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- ERBB2 | c.1021+62C>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GOSR2 | c.40+50C>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- NBPF22P | n.1352G>T | RNA (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156764 C>A | 3'Flank (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
